Somatic mutation profile of tumor specimen 0DJGDZ from CCDI case PBBWEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.6 years (4,966 days).
Specimen 0DJGDZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd89d38-59a0-4fff-baae-68f2c75b771a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG6X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c331427-1a43-4b88-9c19-1e7e366f2e6a

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WFDC9 | c.237C>T p.N79= | Splice Region (SNP) | VAF 56/730 reads (8%) | catalogued as rs557112902, COSV58096107; called by muse, mutect2
- ATP2B2 | c.1049C>T p.P350L (on ENST00000352432; = p.P316L on NM_001683.5) | Missense Mutation (SNP) | VAF 54/696 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBF1 | c.3085-12G>A | Intron (SNP) | VAF 33/376 reads (9%) | catalogued as rs775184468; called by muse, mutect2
- GSE1 | c.*42T>C | 3'UTR (SNP) | VAF 26/256 reads (10%) | catalogued as COSV53672075; called by muse, mutect2
